Somatic mutation profile of tumor specimen TCGA-DY-A1DD-01A (aliquot TCGA-DY-A1DD-01A-21D-A152-10) from TCGA case TCGA-DY-A1DD, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 77.1 years (28,159 days).
Specimen TCGA-DY-A1DD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3906dbd3-5200-4336-8060-c51f11306fbd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DY-A1DD-10A (Blood Derived Normal), aliquot TCGA-DY-A1DD-10A-01D-A152-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/01cbf2d6-3313-4a16-96d9-090877fe531f

The open-access MAF lists 130 somatic variants for this specimen: 100 protein-altering or splice-affecting, 28 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 92, Silent 28, Frame Shift Ins 3, Nonsense Mutation 2, Frame Shift Del 2, Intron 1, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 27/29 reads (93%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB8 | c.439G>T p.V147F (on ENST00000297504 / NM_001282291.2; = p.V130F on NM_007188.5) | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0.062); catalogued as COSV52508278; called by muse, mutect2, varscan2
- ADCY8 | c.2878G>A p.A960T | Missense Mutation (SNP) | VAF 34/163 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53919132; called by muse, mutect2, varscan2
- ADCY9 | c.3462C>A p.N1154K | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV53579125; called by muse, mutect2, varscan2
- AGBL4 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779103173, COSV61890672; called by muse, mutect2, varscan2
- AGGF1 | c.1811T>A p.F604Y | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.989); catalogued as COSV57230524; called by muse, mutect2
- AKAP13 | c.6760C>A p.L2254I (on ENST00000394518 / NM_007200.5; = p.L2258I on NM_006738.6) | Missense Mutation (SNP) | VAF 68/93 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV63465229; called by muse, mutect2, varscan2
- APC | c.4031del p.S1344* | Frame Shift Del (DEL) | VAF 31/53 reads (58%) | catalogued as CM058101, COSV57323283, COSV57323895, COSV57365719; called by mutect2, pindel, varscan2
- ARHGAP27 | c.1022A>T p.E341V | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.676); catalogued as COSV100976628; called by muse, mutect2, varscan2
- ASH1L | c.1468T>G p.L490V | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV100853606; called by muse, mutect2, varscan2
- ASTN2 | c.1865T>C p.V622A (on ENST00000313400 / NM_001365069.1; = p.V571A on NM_014010.5) | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as COSV57801627; called by muse, mutect2, varscan2
- ATAD2 | c.1047C>G p.N349K | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV54884585; called by muse, mutect2, varscan2
- ATP10A | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 28/39 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs756116018, COSV63512850; called by muse, mutect2, varscan2
- BRD1 | c.2988A>T p.R996S (on ENST00000216267 / NM_001349940.1; = p.R1127S on NM_001304808.3) | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53460018; called by muse, mutect2, varscan2
- BRINP2 | c.1939C>T p.R647W | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64175333; called by muse, mutect2, varscan2
- CCNB3 | c.2452G>C p.E818Q | Missense Mutation (SNP) | VAF 50/190 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.636); catalogued as COSV52077479; called by muse, mutect2, varscan2
- CDHR2 | c.1667T>A p.L556Q | Missense Mutation (SNP) | VAF 29/35 reads (83%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV56142613; called by muse, mutect2, varscan2
- CFAP206 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as COSV51532449; called by muse, mutect2, varscan2
- CFAP69 | c.468G>C p.R156S | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV60184806, COSV60187228; called by muse, mutect2, varscan2
- CGGBP1 | c.451C>T p.L151F | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.934); catalogued as COSV58852572; called by muse, mutect2
- COL27A1 | c.4781G>A p.R1594H | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs375311559; called by muse, mutect2, varscan2
- DES | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs748742357, COSV64660787; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAI2 | c.914T>A p.I305N | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.372); catalogued as COSV100210074; called by muse, mutect2, varscan2
- DPYSL4 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1208652939, COSV58308999; called by muse, mutect2, varscan2
- EIF4E | c.410T>A p.L137H | Missense Mutation (SNP) | VAF 11/305 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55188377; called by muse, mutect2
- FAIM | c.158C>T p.T53I | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.22); catalogued as rs767931243, COSV58158910; called by muse, mutect2, varscan2
- FBN2 | c.2938T>A p.C980S | Missense Mutation (SNP) | VAF 40/44 reads (91%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV52532398; called by muse, mutect2, varscan2
- FBN3 | c.2413C>G p.L805V | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as rs1008262241, COSV99561868; called by muse, mutect2
- FBN3 | c.928G>A p.G310S | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.991); catalogued as rs778441811, COSV54467718; called by muse, mutect2, varscan2
- FOLH1 | c.1712A>C p.K571T | Missense Mutation (SNP) | VAF 16/283 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.047); catalogued as COSV99923956; called by muse, mutect2
- FRMPD3 | c.1741G>A p.E581K | Missense Mutation (SNP) | VAF 89/148 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as rs750852072, COSV99345917; called by muse, mutect2, varscan2
- FRY | c.1310T>G p.L437R | Missense Mutation (SNP) | VAF 105/428 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66575474; called by muse, mutect2, varscan2
- GAS2L3 | c.631G>T p.E211* | Nonsense Mutation (SNP) | VAF 19/39 reads (49%) | catalogued as COSV57156719, COSV57158379; called by muse, mutect2, varscan2
- GAS2L3 | c.632A>G p.E211G | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.99); PolyPhen benign (0.009); catalogued as COSV57158386; called by muse, mutect2, varscan2
- GRK1 | c.751G>A p.V251M | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs936018736, COSV59551630; called by muse, mutect2, varscan2
- GUCY1A1 | c.1606G>T p.G536W | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56654635; called by muse, mutect2, varscan2
- H2AB1 | c.311C>T p.T104M | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as COSV100371838; called by mutect2, varscan2
- HECW1 | c.3740C>T p.P1247L | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs759660521, COSV67839496; called by mutect2, varscan2
- HRG | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 79/181 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs759137427, COSV51646967; called by muse, mutect2, varscan2
- ITGA9 | c.337G>A p.G113R | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs759719660, COSV53248471; called by muse, mutect2, varscan2
- KCNH8 | c.1001G>A p.R334H | Missense Mutation (SNP) | VAF 53/139 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60471464; called by muse, mutect2, varscan2
- KCNQ5 | c.2646G>T p.E882D | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as COSV59673911; called by muse, mutect2, varscan2
- LHFPL4 | c.682G>A p.G228R | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.956); catalogued as rs756477849, COSV99805693; called by muse, mutect2, varscan2
- LINGO2 | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs906339987, COSV58057254, COSV58061032; called by muse, mutect2, varscan2
- MAOB | c.1327G>A p.G443R | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65206335; called by muse, mutect2, varscan2
- MAP2 | c.4420dup p.T1474Nfs*22 | Frame Shift Ins (INS) | VAF 14/38 reads (37%) | catalogued as rs1476495251; called by mutect2, varscan2
- MAP4K1 | c.1886C>A p.T629K | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.385); catalogued as COSV67711926; called by muse, mutect2, varscan2
- MDC1 | c.2309C>T p.T770M | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as rs529970009, COSV64525519; called by muse, mutect2, varscan2
- MEX3B | c.639C>A p.N213K | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV61663998; called by mutect2, varscan2
- MIA2 | c.40A>G p.I14V | Missense Mutation (SNP) | VAF 88/96 reads (92%) | SIFT deleterious (0.05); PolyPhen benign (0.112); catalogued as COSV54485265; called by muse, mutect2, varscan2
- MINDY1 | c.682G>T p.V228F | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.853); catalogued as COSV56500195; called by muse, mutect2, varscan2
- MXRA5 | c.7052A>G p.K2351R | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.286); catalogued as COSV54243797; called by muse, mutect2, varscan2
- NAAA | c.918G>T p.K306N | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.705); catalogued as COSV54433278; called by muse, mutect2, varscan2
- NBPF3 | c.1411G>T p.D471Y | Missense Mutation (SNP) | VAF 15/326 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs1409094381, COSV59062268; called by muse, mutect2
- NID2 | c.3118G>A p.V1040M | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs1461741815, COSV53500270; called by muse, mutect2, varscan2
- NOS1 | c.1448A>C p.Q483P | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57617815; called by muse, mutect2, varscan2
- NSD2 | c.469A>T p.N157Y | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.176); catalogued as COSV56394035; called by muse, mutect2, varscan2
- PCDH9 | c.1066C>G p.P356A | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100123596; called by muse, mutect2
- PCLO | c.735A>T p.E245D | Missense Mutation (SNP) | VAF 158/598 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.21); catalogued as COSV61653496; called by muse, mutect2, varscan2
- PCNT | c.4474C>T p.R1492C | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs764560918, COSV64031212; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PDK4 | c.572T>C p.I191T | Missense Mutation (SNP) | VAF 48/189 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs138077797; called by muse, mutect2, varscan2
- PIK3CG | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as rs1339698935, COSV63249355; called by muse, mutect2, varscan2
- PLEKHH2 | c.2356G>C p.E786Q | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as COSV56758197; called by muse, mutect2, varscan2
- PLXNA3 | c.2936+1G>T p.X979_splice | Splice Site (SNP) | VAF 6/97 reads (6%) | catalogued as COSV63754991; called by muse, mutect2
- POGLUT2 | c.176G>A p.G59E | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.911); catalogued as COSV57281337; called by muse, mutect2, varscan2
- PPP2R2B | c.62C>T p.A21V (on ENST00000394409; = p.A87V on NM_181674.2) | Missense Mutation (SNP) | VAF 31/44 reads (70%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60772773; called by muse, mutect2, varscan2
- PRDM4 | c.2149T>A p.L717I | Missense Mutation (SNP) | VAF 47/149 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV57306900; called by muse, mutect2, varscan2
- PRKAG1 | c.896G>A p.R299Q | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60291524; called by muse, mutect2, varscan2
- PSEN1 | c.289G>A p.V97M | Missense Mutation (SNP) | VAF 92/243 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs63750852, CM056038, COSV56196027; called by muse, mutect2, varscan2
- RDX | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as rs142346566, COSV58193116; called by muse, mutect2, varscan2
- RFTN2 | c.202A>T p.N68Y | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.163); catalogued as COSV54391373; called by muse, mutect2
- RNASE3 | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.69); PolyPhen benign (0.036); catalogued as rs758816325, COSV58959188; called by muse, mutect2, varscan2
- RPAP2 | c.599T>G p.F200C | Missense Mutation (SNP) | VAF 80/162 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV101532189; called by muse, mutect2, varscan2
- RPS6 | c.380C>A p.T127N | Missense Mutation (SNP) | VAF 36/48 reads (75%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as rs778272571, COSV59548373; called by muse, mutect2, varscan2
- SEC22C | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.726); catalogued as rs777387356, COSV52566026; called by muse, mutect2, varscan2
- SERPINB6 | c.1003G>A p.V335M (on ENST00000612421 / NM_001271823.2; = p.V316M on NM_004568.6) | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.493); catalogued as rs550855004, COSV59566693; called by muse, mutect2, varscan2
- SLC10A3 | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 62/212 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as rs781892464, COSV54836885; called by muse, mutect2, varscan2
- SLC22A14 | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756552298, COSV56196592; called by muse, mutect2, varscan2
- SMAD4 | c.1283A>T p.K428M | Missense Mutation (SNP) | VAF 27/36 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV61684944, COSV61685775, COSV61687658; called by muse, mutect2, varscan2
- SMAD7 | c.920G>T p.S307I | Missense Mutation (SNP) | VAF 26/33 reads (79%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV100053070; called by muse, mutect2, varscan2
- SNX7 | c.1130C>T p.P377L | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs983531719, COSV60265983; called by muse, mutect2, varscan2
- STPG1 | c.902C>T p.P301L (on ENST00000337248 / NM_001199013.2; = p.P254L on NM_178122.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.34); PolyPhen benign (0.157); catalogued as rs766695337, COSV50222014; called by muse, mutect2, varscan2
- SUN3 | c.423G>T p.K141N | Missense Mutation (SNP) | VAF 159/232 reads (69%) | SIFT tolerated (0.09); PolyPhen benign (0.115); catalogued as COSV52052584; called by muse, mutect2, varscan2
- SUPT20H | c.1373G>T p.G458V (on ENST00000350612 / NM_001014286.3; = p.G459V on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/191 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV62248855; called by muse, mutect2, varscan2
- TNR | c.700C>T p.R234W | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as rs371035988, COSV54876906; called by muse, mutect2, varscan2
- TRIP10 | c.967T>A p.F323I | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as COSV57574124; called by muse, mutect2, varscan2
- TRPV6 | c.2056C>T p.R686C | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs763838443, COSV63890520; called by muse, mutect2, varscan2
- UBQLN2 | c.185C>T p.S62L | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57740233; called by muse, mutect2, varscan2
- UMODL1 | c.3571G>A p.G1191S (on ENST00000408910 / NM_001004416.2; = p.G1319S on NM_173568.3) | Missense Mutation (SNP) | VAF 27/34 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201879010, COSV68570515; called by muse, mutect2, varscan2
- UNC13D | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0.05); PolyPhen benign (0.036); catalogued as rs764975268, COSV52886281; called by muse, mutect2, varscan2
- UNC45B | c.325C>T p.R109W | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs774414887, COSV52098827; called by muse, mutect2, varscan2
- URGCP | c.1552G>A p.V518M (on ENST00000453200 / NM_001077663.3; = p.V509M on NM_017920.4) | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.188); catalogued as rs1007910860, COSV56250758; called by muse, mutect2, varscan2
- VEPH1 | c.2113C>A p.P705T | Missense Mutation (SNP) | VAF 45/93 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1273160676, COSV62881198; called by muse, mutect2, varscan2
- WDFY3 | c.8326G>A p.D2776N | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV55709440; called by muse, mutect2, varscan2
- ZNF385B | c.131A>G p.K44R | Missense Mutation (SNP) | VAF 86/92 reads (93%) | SIFT tolerated (0.13); PolyPhen benign (0.113); catalogued as rs373649075; called by muse, mutect2, varscan2
- ZNF80 | c.493G>T p.E165* | Nonsense Mutation (SNP) | VAF 28/55 reads (51%) | catalogued as COSV100352166, COSV57360801, COSV57362004; called by muse, mutect2, varscan2
- ZSWIM4 | c.2219G>A p.R740Q | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.541); catalogued as rs1410482866, COSV54324528; called by muse, mutect2, varscan2
- DZANK1 | c.1422_1426del p.S474Rfs*25 (on ENST00000262547 / NM_001099407.1; = p.S281Rfs*25 on NM_018152.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 83/105 reads (79%) | called by mutect2, pindel, varscan2
- KIT | c.782dup p.S261Rfs*6 | Frame Shift Ins (INS) | VAF 31/91 reads (34%) | called by mutect2, pindel, varscan2
- TMEM52B | c.148dup p.V50Gfs*36 (on ENST00000381923 / NM_001079815.1; = p.V30Gfs*36 on NM_153022.4) | Frame Shift Ins (INS) | VAF 34/116 reads (29%) | called by mutect2, pindel, varscan2
- AGGF1 | c.1809T>A p.T603= | Silent (SNP) | VAF 12/108 reads (11%) | catalogued as rs762815931, COSV57230519; called by muse, mutect2
- AGK | c.585C>A p.I195= | Silent (SNP) | VAF 60/206 reads (29%) | catalogued as rs1185260310, COSV62595428; called by muse, mutect2, varscan2
- ALLC | c.831T>C p.I277= | Silent (SNP) | VAF 40/90 reads (44%) | catalogued as COSV52997006, COSV99378374; called by muse, mutect2, varscan2
- ANAPC2 | c.474C>T p.R158= | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as rs1451549255, COSV58808520; called by muse, mutect2, varscan2
- CD163L1 | c.342T>C p.D114= | Silent (SNP) | VAF 22/78 reads (28%) | catalogued as COSV58026702; called by muse, mutect2
- CNMD | c.225C>A p.V75= | Silent (SNP) | VAF 10/240 reads (4%) | called by muse, mutect2
- CPO | c.591A>G p.R197= | Silent (SNP) | VAF 143/168 reads (85%) | catalogued as COSV55940955; called by muse, mutect2, varscan2
- FAT4 | c.618C>A p.G206= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as COSV67881962, COSV67894846; called by muse, mutect2, varscan2
- FGFRL1 | c.1143C>T p.I381= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as rs146112374; called by muse, mutect2, varscan2
- FOXL2NB | c.162C>T p.I54= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as COSV57729006; called by muse, mutect2, varscan2
- GEMIN5 | c.2232G>A p.K744= | Silent (SNP) | VAF 118/170 reads (69%) | catalogued as COSV53563282; called by mutect2, varscan2
- IMP4 | c.489G>A p.T163= | Silent (SNP) | VAF 22/44 reads (50%) | catalogued as rs753446172, COSV52091342; called by muse, mutect2, varscan2
- LGR5 | c.1131G>A p.Q377= | Silent (SNP) | VAF 20/74 reads (27%) | catalogued as COSV99878536; called by muse, mutect2, varscan2
- PAQR9 | c.630C>T p.R210= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV61418760; called by muse, mutect2, varscan2
- PRDM14 | c.1233C>T p.Y411= | Silent (SNP) | VAF 31/84 reads (37%) | catalogued as COSV52570971, COSV52574123; called by muse, mutect2, varscan2
- PTCD1 | c.942G>A p.G314= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs1478278465, COSV99464562; called by muse, mutect2
- RFC1 | c.3279G>A p.S1093= (on ENST00000381897 / NM_001363496.2; = p.S1092= on NM_002913.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 108/282 reads (38%) | catalogued as rs201096166, COSV56468155; called by muse, mutect2, varscan2
- RIN3 | c.1074G>A p.A358= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs748276702, COSV53653070; called by muse, mutect2, varscan2
- RNF26 | c.147G>A p.T49= | Silent (SNP) | VAF 73/223 reads (33%) | catalogued as COSV60991116; called by muse, mutect2, varscan2
- ROGDI | c.265C>T p.L89= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as COSV58928389; called by muse, mutect2, varscan2
- SLC26A4 | c.987A>G p.K329= | Silent (SNP) | VAF 31/122 reads (25%) | catalogued as COSV55918677; called by muse, mutect2, varscan2
- SUN1 | c.663C>T p.D221= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs759581690, COSV61779436; called by muse, mutect2
- SYT7 | c.453G>A p.T151= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs372903756; called by muse, mutect2, varscan2
- TAL1 | c.975C>T p.A325= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as rs768232051, COSV99596406; called by muse, mutect2, varscan2
- TNC | c.4941C>T p.F1647= | Silent (SNP) | VAF 39/109 reads (36%) | catalogued as rs201689087, COSV60788203; called by muse, mutect2, varscan2
- TRIM11 | c.447G>A p.Q149= | Silent (SNP) | VAF 42/89 reads (47%) | catalogued as COSV52859224; called by muse, mutect2, varscan2
- URGCP | c.1389C>T p.D463= (on ENST00000453200 / NM_001077663.3; = p.D454= on NM_017920.4) | Silent (SNP) | VAF 121/173 reads (70%) | catalogued as rs980857331, COSV56250777, COSV56252188; called by muse, mutect2, varscan2
- XKR6 | c.1311G>A p.R437= | Silent (SNP) | VAF 20/26 reads (77%) | catalogued as COSV58658292; called by muse, mutect2, varscan2
- ADARB2 | c.101-177506C>T | Intron (SNP) | VAF 48/64 reads (75%) | called by muse, mutect2, varscan2
- RPP38 | chr10:15096523 G>T | 5'Flank (SNP) | VAF 59/133 reads (44%) | called by muse, mutect2, varscan2
